Somatic mutation profile of tumor specimen TCGA-KO-8414-01A (aliquot TCGA-KO-8414-01A-11D-2310-10) from TCGA case TCGA-KO-8414, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 50.7 years (18,502 days).
Specimen TCGA-KO-8414-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be6a23d2-b522-493c-9d4b-cf64b3a2d3f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KO-8414-11A (Solid Tissue Normal), aliquot TCGA-KO-8414-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dee0bb24-9989-43dc-8e53-01346005e55b

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 13, Silent 3, Frame Shift Del 1, Nonsense Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSMD2 | c.7805A>G p.E2602G | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.93); catalogued as COSV99590027; called by muse, mutect2, varscan2
- FBXL5 | c.571A>G p.K191E | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.98); catalogued as COSV100377874; called by muse, mutect2, varscan2
- GGCT | c.88_89del p.R30Dfs*20 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as rs748515382; called by pindel, varscan2
- GPR35 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 30/36 reads (83%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.943); catalogued as rs377190882, COSV100166477, COSV100166776; called by muse, mutect2, varscan2
- GRM3 | c.2399C>T p.T800M | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs376384427; called by muse, mutect2, varscan2
- IGHD3-9 | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 29/172 reads (17%) | catalogued as rs370221435; called by muse, mutect2, varscan2
- LPIN1 | c.194T>A p.V65D | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99877583; called by muse, mutect2
- PCDH15 | c.4543T>G p.Y1515D (on ENST00000644397 / NM_001354429.2; = p.I1475M on NM_001142770.3) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64705793; called by muse, mutect2, varscan2
- PEG3 | c.2807G>A p.R936H | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); catalogued as rs140722468, COSV99687725; called by muse, mutect2, varscan2
- PTPRN2 | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1047290785, COSV67026880; called by muse, mutect2
- RCOR2 | c.557T>C p.M186T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100036205; called by muse, mutect2, varscan2
- SETD1A | c.3401C>G p.P1134R | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs1261769587, COSV52689776, COSV99352994; called by muse, mutect2, varscan2
- SYNDIG1 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762805806, COSV65235257; called by muse, mutect2, varscan2
- TRAPPC9 | c.1496A>G p.E499G | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101227459; called by muse, mutect2
- APMAP | c.39_50del p.R14_V17del | In Frame Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, varscan2
- TPO | c.2074T>C p.S692P | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.272); called by muse, mutect2
- FEZ1 | c.132C>T p.S44= | Silent (SNP) | VAF 27/123 reads (22%) | catalogued as rs558361561, COSV54029956; called by muse, mutect2, varscan2
- GRWD1 | c.705T>C p.C235= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV99474381; called by muse, varscan2
- OR2AT4 | c.675C>T p.H225= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as COSV100532342; called by muse, mutect2
